Somatic mutation profile of tumor specimen TCGA-HT-7472-01A (aliquot TCGA-HT-7472-01A-11D-2024-08) from TCGA case TCGA-HT-7472, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.2 years (13,968 days).
Specimen TCGA-HT-7472-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc2118cb-5bd8-47ea-975f-a759f2a4bc36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7472-10A (Blood Derived Normal), aliquot TCGA-HT-7472-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ec0345e-cdf0-4d0d-988d-89115687db05

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Frame Shift Del 2, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/78 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 16/19 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2780G>A p.G927D | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55000262; called by muse, mutect2, varscan2
- F13A1 | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53559139, COSV99342704; called by muse, mutect2, varscan2
- MYH15 | c.629T>C p.I210T | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1468974093, COSV56310983; called by muse, mutect2, varscan2
- MYLK3 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV67364265; called by muse, mutect2, varscan2
- NCOA3 | c.2525C>G p.S842* | Nonsense Mutation (SNP) | VAF 45/115 reads (39%) | catalogued as COSV59068994, COSV59069225; called by muse, mutect2, varscan2
- OR52B6 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV61447853; called by muse, mutect2, varscan2
- OSBPL10 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV67339687; called by muse, mutect2
- WNT7A | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV53199046; called by muse, mutect2, varscan2
- ATRX | c.3268_3271del p.E1090Rfs*27 | Frame Shift Del (DEL) | VAF 99/163 reads (61%) | called by mutect2, pindel, varscan2
- MKLN1 | c.853_856del p.V285Ifs*20 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- ZNF148 | c.852dup p.L285Tfs*3 | Frame Shift Ins (INS) | VAF 33/92 reads (36%) | called by mutect2, varscan2
- ANGPTL2 | c.1098G>C p.L366= | Silent (SNP) | VAF 102/321 reads (32%) | catalogued as COSV52222714; called by muse, mutect2, varscan2
- BCOR | c.378G>C p.P126= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV60708062; called by muse, mutect2, varscan2
- GAPVD1 | c.4350T>C p.A1450= (on ENST00000394104; = p.A1459= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as rs1361744462, COSV52923290; called by muse, mutect2, varscan2
- OR8I2 | c.798G>A p.S266= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as rs1187305308, COSV56167529; called by muse, mutect2
- POLR3H | c.192C>T p.G64= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs771472417, COSV61749488; called by muse, mutect2, varscan2
- RPS6KC1 | c.1821T>C p.D607= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV65299617; called by muse, mutect2, varscan2
- CTHRC1 | c.150+777A>G | Intron (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100373063; called by muse, mutect2, varscan2
